Surgical pathology report (de-identified scan), TCGA case TCGA-B0-4690, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-B0-4690-01A (Primary Tumor).

FINAL DIAGNOSIS

LYMPH NODE, EXCISION -

NO EVIDENCE OF NEOPLASIA IN 3 (0/3) LYMPH NODES.

PART 2:

KIDNEY, RIGHT, NEPHRECTOMY -

- A. RENAL CELL CARCINOMA, CLEAR CELL TYPE WITH SARCOMATOID FEATURES.
- B. FUHRMAN NUCLEAR GRADE IS 3 of 4.
- C. THE GREATEST DIAMETER OF THE NEOPLASM IS 12.0 cm.
- D. THE NEOPLASM EXTENDS INTO THE PERIRENAL AND PERIPELVIC FAT.
- E. NO EVIDENCE OF ANGIOLYMPHATIC INVASION IS IDENTIFIED.
- F. CARCINOMA GROSSLY EXTENDS INTO THE RENAL VEIN.
- G. ALL OTHER SURGICAL MARGINS ARE FREE OF THE NEOPLASM.
- H. NON-NEOPLASTIC KIDNEY SHOWS CHRONIC INTERSTITIAL INFLAMMATION, GLOMERULOSCLEROSIS, AND THYROIDIZATION.
-
- I. ADRENAL GLAND WITH RENAL CELL CARCINOMA (See Comment).
- J. NO EVIDENCE OF NEOPLASIA IN 3 (0/3) LYMPH NODES.
- K. TNM STAGE: pT3b N0 MX.

Final Diagnosis

ESOPHAGUS, NODULE, BIOPSY -

- A. REACTIVE / HYPERPLASTIC GASTRIC MUCOSA AND SCANT INFLAMED SQUAMOUS MUCOSA.
- B. NEGATIVE FOR INTESTINAL METAPLASIA.

Source: NCI Genomic Data Commons file 51c9c1ef-3969-4e30-9cef-fc1f6302f5c6 (TCGA-B0-4690.DD5521F2-076A-43A4-8DCA-A16545C9E77D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).